Somatic mutation profile of tumor specimen TCGA-S7-A7WM-01A (aliquot TCGA-S7-A7WM-01A-12D-A35I-08) from TCGA case TCGA-S7-A7WM, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 76.6 years (27,984 days).
Specimen TCGA-S7-A7WM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b779510d-f2d3-4aed-b978-b84e51a79192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WM-10A (Blood Derived Normal), aliquot TCGA-S7-A7WM-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8066b842-af93-456a-91e3-7355ae28cf3b

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.402); catalogued as rs1180501933; called by muse, mutect2, varscan2
- AHCTF1 | c.5281A>G p.M1761V (on ENST00000366508; = p.M1735V on NM_015446.5) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1294855539; called by muse, mutect2, varscan2
- LRRIQ1 | c.1877A>G p.E626G | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs1163333836; called by muse, mutect2, varscan2
- SERPINB9 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs144457124; called by muse, mutect2, varscan2
- BOD1L1 | c.7642G>T p.E2548* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- CNTN2 | c.1121A>T p.E374V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- MIGA2 | c.1630A>C p.T544P | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- NF1 | c.1473_1474insTT p.L492Ffs*7 | Frame Shift Ins (INS) | VAF 19/37 reads (51%) | called by mutect2, pindel, varscan2
- SDHA | c.1958A>C p.D653A | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2
- SEMA6D | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFTPH | c.2373A>G p.T791= | Silent (SNP) | VAF 58/131 reads (44%) | called by muse, mutect2, varscan2
- TMEM105 | n.800C>A | RNA (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.10361-5084C>T | Intron (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
